CCDI case PBBHIL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7563d697-57b7-4e47-8aad-6f105de9a88f

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 3.8 years (1,386 days).

Biospecimens (3 samples)
- Sample 0D8BTF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D8BTK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0D8BTL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
